Somatic mutation profile of tumor specimen TARGET-10-PANTWC-09A (aliquot TARGET-10-PANTWC-09A-01D) from TARGET case TARGET-10-PANTWC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,546 days).
Specimen TARGET-10-PANTWC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 096d2e7a-9e48-4365-b8a5-f226d541b640.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANTWC-14A (Bone Marrow Normal), aliquot TARGET-10-PANTWC-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19ba9ce2-d47b-4eef-9ff8-0a5962e63b19

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, 3'UTR 1, Nonsense Mutation 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 7/47 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PLEKHG4B | c.1147G>A p.A383T (on ENST00000283426; = p.A739T on NM_052909.5) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs558371500, COSV52043468; called by muse, mutect2, varscan2
- POGLUT2 | c.1388A>G p.Y463C | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770990781; called by muse, mutect2, varscan2
- SI | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as rs747388124, COSV52303659; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13B | c.6616G>A p.G2206R | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1423290124; called by muse, mutect2, varscan2
- ZEB2 | c.3113A>G p.H1038R | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57953045; called by muse, mutect2, varscan2
- EPHA1 | c.1639G>T p.E547* | Nonsense Mutation (SNP) | VAF 41/80 reads (51%) | called by muse, mutect2, varscan2
- HNF1A | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2D | c.10510_10511insGCCG p.E3504Gfs*4 | Frame Shift Ins (INS) | VAF 22/80 reads (28%) | called by mutect2, pindel, varscan2
- OR1J4 | c.338T>G p.F113C | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- UBE2F | c.430A>T p.N144Y | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1QTNF2 | c.660C>T p.N220= (on ENST00000393975; = p.N175= on NM_031908.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as rs755115029; called by muse, mutect2, varscan2
- ESPN | c.2004G>A p.T668= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs367594266; called by muse, mutect2
- OPN4 | c.345C>T p.S115= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs994273641, COSV54118307; called by muse, mutect2, varscan2
- TIAM1 | c.2247T>A p.V749= | Silent (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- ALB | c.*56A>C | 3'UTR (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- PTPRB | chr12:70520208 C>T | 3'Flank (SNP) | VAF 15/99 reads (15%) | catalogued as rs554335440, COSV99716947; called by muse, mutect2, varscan2
